Surgical pathology report (de-identified scan), TCGA case TCGA-41-2573, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-2573-01A (Primary Tumor).

[REDACTED]
[REDACTED] (GBM)

SPECIMEN

- A. Right parieto-occipital tumor
- B. Tissue procurement specimen
- C. Right parieto-occipital lobe

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right brain tumor.

FROZEN SECTION DIAGNOSIS

FSA) Right parieto-occipital - At least anaplastic astrocytoma (grade 3); Final grade deferred to permanent sections. [REDACTED]
[REDACTED]

GROSS DESCRIPTION

- A. Submitted fresh for fresh as part A "right parieto-occipital tumor" are multiple and minute fragments of mucoid tan and reddish brown tissue each approximately 1 to 2 mm. in greatest extent submitted entirely for frozen section.
- B. Tissue procurement specimen.
- C. Received in formalin, labeled "right parieto-occipital tumor". The specimen consists of multiple brown-tan irregular soft friable tissue fragments which have an aggregate measurement of 1.0cm. The specimen is entirely submitted in one cassette. AS-1. [REDACTED]
[REDACTED]

MICROSCOPIC DESCRIPTION

Microscopic sections of the right parietal occipital tumor reveals a malignant astrocytic neoplasm. It is characterized by a sheet-like pattern of growth of markedly pleomorphic malignant astrocytes demonstrating cytomegaly, nucleomegaly, multinucleation and frequent mitotic figures. There is evidence of tumoral neovascularity and areas of necrosis within the

MICROSCOPIC DESCRIPTION

tumor. Based on these histologic features the lesion is categorized as a Glioblastoma multiforme (Astrocytoma WHO grade IV).

4x2, 14

DIAGNOSIS

- A. and C. Brain, right parietal occipital, resection of lesion: Glioblastoma multiforme (Astrocytoma WHO Grade IV).
[REDACTED]

Source: NCI Genomic Data Commons file 7ab6955b-283e-4dcd-a70a-ca24337357cf (TCGA-41-2573.177CDF51-1694-4197-B0F3-1C97DFA38BBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).